Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A4AB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A4AB-01B (Primary Tumor).

[page 1 of 7]
Name
Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. LEFT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED - FS-
- B. LEFT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED -
- C. RIGHT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED - FS-
- D. RIGHT DISTAL URETER - MARGIN IS INKED - NFS-
- E. LEFT URETEROVESICAL JUNCTION-
- F. LEFT PELVIC LYMPH NODES-
- G. RIGHT PELVIC LYMPH NODES-
- H. BLADDER AND PROSTATE-

1cD-0-3

carcinoma, urothelial, NOS 8/20/3
Site: bladder wall, posterior C67.4

fw 9/24/12

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED - FS-

CROSS SECTION OF URETER WITH NO TUMOR SEEN.

- B. LEFT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED - NFS-

INVASIVE UROTHELIAL CARCINOMA INVOLVING THE EXTERIOR URETERAL MUSCULARIS PROPRIA AND PERIURETERAL ADIPOSE TISSUE WITH EXTENSIVE PRESENCE ON THE PERIURETERAL SOFT TISSUE MARGIN OF EXCISION.

THE URETER UROTHELIUM IS UNREMARKABLE.

- C. RIGHT DISTAL URETER WITH URETERAL TUMOR - MARGIN IS INKED - FS-

CROSS SECTION OF URETER WITH NO TUMOR SEEN.

- D. RIGHT DISTAL URETER - MARGIN IS INKED - NFS-
- URETER WALL WITH NO TUMOR SEEN.

Prepared for

[page 2 of 7]
E. LEFT URETEROVESICAL JUNCTION-
INVASIVE UROTHELIAL CARCINOMA PRESENT IN THE SOFT TISSUE
FRAGMENTS OF THE URETEROVESICAL TISSUE.

F. LEFT PELVIC LYMPH NODES-
ONE LYMPH NODE WITH NO TUMOR SEEN (0/1).

G. RIGHT PELVIC LYMPH NODES-
ONE LYMPH NODE WITH NO TUMOR SEEN (0/1).

H. BLADDER AND PROSTATE-
INVASIVE UROTHELIAL CARCINOMA, HIGH GRADE.

TUMOR SITE: POSTERIOR WALL, URINARY BLADDER.

SQUAMOUS DIFFERENTIATION: PRESENT.

GLANDULAR DIFFERENTIATION: NOT PRESENT.

TUMOR SIZE: 10 CM.

HISTOLOGIC GRADE: 3/3.

EXTRAVESICULAR MASS: MACRO-SCOPICALLY PRESENT.

DIRECT INVASION OF PROSTATIC STROMA: PRESENT.

INVASION OF SEMINAL VESICLE: PRESENT.

INVASION OF PELVIC OR ABDOMINAL WALL: NOT PRESENT.

SPECIMEN TYPE: CYSTOPROSTATECTOMY

TNM STAGE: pT4a, pN0, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 2

LYMPHATIC (SMALL VESSEL) INVASION: PRESENT.

PERINEURAL INVASION: PRESENT.

ASSOCIATED EPITHELIAL LESIONS: NOT IDENTIFIED.

UROTHELIAL CARCINOMA IS EXTENSIVELY PRESENT AT THE
PERIVESICULAR, PROSTATIC AND PERIURETERAL SOFT TISSUE MARGINS OF
EXCISION. DISTAL URETERAL AND URETHRAL MARGINS OF EXCISION ARE
NEGATIVE FOR TUMOR.

INCIDENTAL ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC

Prepared

[page 3 of 7]
EXTENSION SEEN.

TUMOR SITE: RIGHT, MOSTLY IN PERIPHERAL ZONE.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10.

SEVERITY IN EXTENT OF TUMOR: 2/5.

TNM STAGE: pT2a, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: NOT PRESENT.

NO PROSTATIC CARCINOMA SEEN IN SEMINAL VESICLES.

NO PROSTATIC CARCINOMA SEEN AT SPECIMEN MARGINS.

Signed Others

Frozen Section

A. LEFT DISTAL URETER WITH URETERAL TUMOR, MARGIN IS INKED, FS:
-PORTION OF URETER WITH MILD CYTOLOGIC ATYPIA WITH FROZEN
ARTIFACT, FAVOR REACTIVE.
-NO DEFINITE CARCINOMA SEEN.

RIGHT DISTAL URETER MARGIN IS INKED. SAME AS ABOVE.

Case Clinical Information
BLADDER CANCER

Gross Description

A. Received in formalin labeled with the patient's name and
"left distal ureter with ureteral tumor FS" consists of a 0.6 cm
frozen section tissue remnant. Wrapped and submitted in A1.
B. Received in formalin labeled with the patient's name and
"left distal ureter with ureteral tumor NFS" consists of a

Prepared for

[page 4 of 7]
tubular structure of tan-pink soft tissue consistent with ureter measuring 4 cm with a maximal diameter of 0.6 cm. Centrally located is a bulging of the structure, and this area is firm upon palpation. The margin has been previously inked by the frozen section pathologist. The area of the bulge is inked orange, and the cut surface reveals a narrowed lumen with the wall having a smooth indurated appearance and measuring 0.4 cm in thickness. The entire specimen is submitted as follows: inked resection margin=B1; opposite resection margin=B2; remainder of the body=B3.

C. Received in formalin labeled with the patient's name and "right distal ureter with ureteral tumor - margin inked - FS" consists of a 0.5 cm frozen section tissue remnant. Wrapped and submitted in C1.

D. Received in formalin labeled with the patient's name and "right distal ureter - margin is inked - NFS" consists of a 0.6 cm fragment of tan, fatty tissue. Wrapped and submitted in D1.

E. Received in formalin labeled with the patient's name and "left ureterovesical junction" consists of an irregular fragment of tan, shaggy tissue measuring 1 x 1 x 0.8 cm. A suture is noted on one edge of the specimen. However, no definitive orientation to the suture is given on the container or the requisition. The specimen is trisected and entirely submitted in E1.

F. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" consists of a 1.5 cm nodule of tan, fatty tissue consistent with lymphoid tissue. Excess fat is trimmed and the nodules is submitted in F1, remaining trimmed fatty tissue in F2.

G. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" consistent of two nodules of tan, fatty tissue consistent with lymphoid tissue, each measuring 1 cm. The excess fat is trimmed, and the two nodes are submitted in G1-G2, one lymph node each cassette.

H. Received in formalin labeled with the patient's name and "bladder and prostate" consists of a radical cystectomy specimen with attached fatty tissue. Overall dimensions of the specimen measure 13 x 10 x 8 cm. The attached prostate measures 5 x 4 x 4 cm. At the area of the attached left seminal vesicals, several sutures are identified and a 3.5 cm defect is noted on the surface on the soft tissue. The left vas deferens measures 7 cm in length. The left seminal vesicle measures 4 x 1 x 1 cm. The right seminal vesicle measures 4.5 x 1 x 1 cm. The right vas deferens measures 6.5 cm in length. The prostatic urethral margin has a shaggy appearance. The specimen is inked blue on the left, black on the right. The left and right ureters are embedded in the fat and have been previously taken for frozen section evaluation. The bladder is opened

[page 5 of 7]
anteriorly, and in the left trigone and left lateral wall a 10 cm ulcerated mass is identified. The remainder of the bladder mucosa has a congested cobblestoned appearance. Cross sectioning into the mass, the cut surface has a very indurated smooth appearance and grossly appears to invade into the fatty tissue. Also, the mass grossly appears to invade into the posterior wall. The posterior aspect of the prostate and cut surface has a very indurated smooth, glistening appearance. This area of the prostate on both left and right sides measures 3 cm. Representative sections of the specimen are submitted as follows: H1=prostatic urethral margin; H2-H4=full thickness cross sections of left posterior wall; H5-H6=left trigone; H7-H10=left lateral wall; H11-H12=left dome; H13-H15=right posterior wall; H16-H17=right trigone; H18-H20=right lateral wall; H21=right dome; H22-H26=full thickness cross sections of left prostate upper mid and lower one-thirds respectively; H27-H33=full thickness cross sections of upper mid and lower one-thirds of right side of prostate. Photographs of the specimen have also been taken

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- G. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- H. AA ROUTINE H&E X1 BLOCK.1

[page 6 of 7]
H&E X1
H. AA ROUTINE H&E X1 BLOCK.2
H&E X1
H. AA ROUTINE H&E X1 BLOCK.3
H&E X1
H. AA ROUTINE H&E X1 BLOCK.4
H&E X1
H. AA ROUTINE H&E X1 BLOCK.5
H&E X1
H. AA ROUTINE H&E X1 BLOCK.6
H&E X1
H. AA ROUTINE H&E X1 BLOCK.7
H&E X1
H. AA ROUTINE H&E X1 BLOCK.8
H&E X1
H. AA ROUTINE H&E X1 BLOCK.9
H&E X1
H. AA ROUTINE H&E X1 BLOCK.10
H&E X1
H. AA ROUTINE H&E X1 BLOCK.11
H&E X1
H. AA ROUTINE H&E X1 BLOCK.12
H&E X1
H. AA ROUTINE H&E X1 BLOCK.13
H&E X1
H. AA ROUTINE H&E X1 BLOCK.14
H&E X1
H. AA ROUTINE H&E X1 BLOCK.15
H&E X1
H. AA ROUTINE H&E X1 BLOCK.16
H&E X1
H. AA ROUTINE H&E X1 BLOCK.17
H&E X1
H. AA ROUTINE H&E X1 BLOCK.18
H&E X1
H. AA ROUTINE H&E X1 BLOCK.19
H&E X1
H. AA ROUTINE H&E X1 BLOCK.20
H&E X1
H. AA ROUTINE H&E X1 BLOCK.21
H&E X1
H. AA ROUTINE H&E X1 BLOCK.22
H&E X1
H. AA ROUTINE H&E X1 BLOCK.23
H&E X1
H. AA ROUTINE H&E X1 BLOCK.24
H&E X1
H. AA ROUTINE H&E X1 BLOCK.25
H&E X1

Prepared for

[page 7 of 7]
H. AA ROUTINE H&E X1 BLOCK.26
H&E X1
H. AA ROUTINE H&E X1 BLOCK.27
H&E X1
H. AA ROUTINE H&E X1 BLOCK.28
H&E X1
H. AA ROUTINE H&E X1 BLOCK.29
H&E X1
H. AA ROUTINE H&E X1 BLOCK.30
H&E X1
H. AA ROUTINE H&E X1 BLOCK.31
H&E X1
H. AA ROUTINE H&E X1 BLOCK.32
H&E X1
H. AA ROUTINE H&E X1 BLOCK.33
H&E X1

Prepared

Dual/Syncronous Primary	☒	

lu
9/11/12

Source: NCI Genomic Data Commons file c2998ca1-13bc-44ce-8c93-88c6181ebeb8 (TCGA-K4-A4AB.A23011FA-CE59-4D74-8EBC-7B02AA30E1D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).